Gene-level copy-number profile of tumor specimen TCGA-GV-A40G-01A from TCGA case TCGA-GV-A40G, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 77.2 years (28,204 days).
Specimen TCGA-GV-A40G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.ca08423e-7217-4460-95d7-3ec9c399ed20.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GV-A40G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/37c8c050-ed13-4d8e-bb5a-c56c91b877c8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 3,244; copy number 2: 14,217; copy number 3: 21,403; copy number 4: 13,534; copy number 5: 4,630; copy number 6: 1,296; copy number 7: 545; copy number 8: 213; copy number 9: 620; copy number 18: 20; copy number 23: 73.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GV-A40G-01A-11D-A23L-01): tumor purity 0.73, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:18,849,258–18,849,707, 1 gene: AC087821.2.
- chr11:103,675,994–104,164,379, 5 genes (within-gene range 0–2): AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,471 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–164,357,364, 890 genes, copy number 7–9 (broad region; genes not listed).
- chr3:145,523,538–168,830,599, 340 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr6:139,614,438–140,205,326, 8 genes, copy number 7: ATP5PBP6, AL390205.1, FILNC1, AL050338.1, AL050338.2, AL357146.1, RNA5SP220, MIR3668.
- chr18:47,390–6,915,716, 140 genes, copy number 8–9 (broad region; genes not listed).
- chr20:43,388,642–45,670,270, 93 genes, copy number 18–23 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,039. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
